Somatic mutation profile of tumor specimen MBCProject_0343_T1_WES (aliquot MBCProject_0343_T1_WES_1) from CMI case MBCProject_0343, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0343_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61cb8edc-15ad-4c6e-a8f5-157b7f31962b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0343_SALIVA (Saliva), aliquot MBCProject_0343_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550bbeed-8b4a-4f12-85f4-7d310b0d9854

The open-access MAF lists 80 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Intron 4, Splice Site 2, 3'UTR 2, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APMAP | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs1005872426; called by muse, mutect2, varscan2
- CEL | c.17G>A p.R6H (on ENST00000673714; = p.R3H on NM_001807.6) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs754771362; called by muse, varscan2
- CSN1S1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.046); catalogued as rs1266295913; called by muse, mutect2, varscan2
- DHDH | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs762549322; called by muse, mutect2, varscan2
- EFS | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373577270; called by muse, mutect2, varscan2
- FAM227B | c.398dup p.I134Dfs*6 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | catalogued as rs745700824; called by mutect2, varscan2
- FBN3 | c.7849C>T p.R2617W | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as rs201196689, COSV54461815; called by muse, mutect2, varscan2
- FBXL8 | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs970417954; called by muse, mutect2, varscan2
- FN1 | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118036; called by muse, mutect2, varscan2
- KLHL34 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs781103451, COSV65279847; called by mutect2, varscan2
- MME | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64707184; called by muse, mutect2, varscan2
- MYO1D | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs1182063726, COSV59018344; called by muse, mutect2
- SEMA3B | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs781798375; called by muse, mutect2, varscan2
- TAF7L | c.403+1G>A p.X135_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV61256320; called by muse, mutect2
- TNFAIP8L1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs922813875; called by muse, mutect2
- TSKS | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754948650; called by muse, mutect2, varscan2
- WFIKKN2 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773394027; called by mutect2, varscan2
- ZNF398 | c.1498C>T p.R500C (on ENST00000475153 / NM_170686.3; = p.R329C on NM_020781.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761838813, COSV60066669; called by muse, mutect2
- ABCA2 | c.1213G>A p.A405T (on ENST00000614293; = p.A375T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2
- ADGRG4 | c.7480G>C p.V2494L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADGRV1 | c.14984T>G p.I4995S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by mutect2, varscan2
- ANK2 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.385); called by muse, varscan2
- ARHGAP25 | c.885C>G p.F295L (on ENST00000409202 / NM_001007231.3; = p.F287L on NM_014882.3) | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CARMIL3 | c.2249A>G p.Q750R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2
- CD1A | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, varscan2
- CFAP54 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CFAP77 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- COL25A1 | c.520T>A p.F174I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DCTN3 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKQ | c.2382C>A p.H794Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DMD | c.10187C>G p.P3396R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GNL2 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- GPR119 | c.344del p.K115Rfs*3 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- HTR1B | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KAT2B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.023); called by muse, mutect2
- KRT39 | c.1429T>G p.Y477D | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MYH13 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NCOR1 | c.1699del p.A567Pfs*23 | Frame Shift Del (DEL) | VAF 78/172 reads (45%) | called by mutect2, pindel, varscan2
- NLRC3 | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- OLFM4 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR4C5 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RX4 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA3 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2
- PSKH2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRB | c.154T>C p.W52R | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF213 | c.5674dup p.Y1892Lfs*40 | Frame Shift Ins (INS) | VAF 76/395 reads (19%) | called by mutect2, pindel, varscan2
- RYR3 | c.8878G>A p.A2960T (on ENST00000389232; = p.A2961T on NM_001036.6) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCYL2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SETD2 | c.1456T>C p.S486P | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPIC | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- SPTA1 | c.3218A>T p.E1073V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TMEM132C | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOGARAM1 | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- TPSD1 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTF2 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP25 | c.996C>T p.I332= (on ENST00000409202 / NM_001007231.3; = p.I324= on NM_014882.3) | Silent (SNP) | VAF 158/364 reads (43%) | called by muse, varscan2
- ARHGAP40 | c.408G>A p.S136= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs546002152, COSV54805571; called by mutect2, varscan2
- CARS2 | c.105C>T p.S35= | Silent (SNP) | VAF 80/160 reads (50%) | catalogued as rs1046292970; called by muse, mutect2, varscan2
- COL21A1 | c.2301G>A p.G767= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs777944369, COSV55169375; called by muse, mutect2, varscan2
- FADS2 | c.1200C>T p.A400= | Silent (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- FLNC | c.6441C>T p.I2147= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as rs762017885; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FOXF1 | c.717C>T p.H239= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99296296; called by muse, mutect2, varscan2
- GZMM | c.108G>A p.S36= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs776715218, COSV99198873; called by mutect2, varscan2
- NUDT10 | c.210G>T p.A70= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PON3 | c.795C>A p.T265= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- PRLR | c.1611C>T p.P537= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as rs1188716314, COSV99184199; called by muse, mutect2
- SERINC5 | c.253C>T p.L85= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- SFRP4 | c.312G>A p.A104= | Silent (SNP) | VAF 24/276 reads (9%) | catalogued as COSV52259605; called by muse, mutect2
- SI | c.5118A>G p.K1706= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- SRSF5 | c.336T>C p.V112= | Silent (SNP) | VAF 86/222 reads (39%) | called by muse, mutect2, varscan2
- AHCY | c.-36C>G | 5'UTR (SNP) | VAF 45/323 reads (14%) | catalogued as rs1488189759; called by muse, mutect2, varscan2
- AIMP1 | c.-26+189G>A | Intron (SNP) | VAF 64/151 reads (42%) | catalogued as rs546179277; called by muse, mutect2, varscan2
- CREB5 | chr7:28409892 C>A | 5'Flank (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*77G>C | 3'UTR (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- KDM5C | c.229-313T>C | Intron (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- NRK | c.-70C>A | 5'UTR (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- PRR14 | c.192+376C>T | Intron (SNP) | VAF 12/133 reads (9%) | catalogued as rs1010263570; called by muse, mutect2
- PTH2 | c.*3G>A | 3'UTR (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- RPGR | c.2520+680G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
